Somatic mutation profile of tumor specimen MP2PRT-PASVKN-TMP1-A (aliquot MP2PRT-PASVKN-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PASVKN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,430 days).
Specimen MP2PRT-PASVKN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) febf0ae2-c0c0-46dd-9c74-f929c35cd67a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASVKN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASVKN-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bf6f5a02-2b23-4284-90dd-dd03eabf3b8e

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 6, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 73/262 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SHROOM2 | c.2234C>T p.P745L | Missense Mutation (SNP) | VAF 221/486 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs981858017, COSV66609291; called by muse, mutect2, varscan2
- ST18 | c.1781A>G p.N594S | Missense Mutation (SNP) | VAF 77/225 reads (34%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.828); catalogued as COSV99390905; called by muse, mutect2, varscan2
- TAS2R14 | c.320A>G p.Y107C | Missense Mutation (SNP) | VAF 29/563 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs769183561; called by muse, mutect2
- FNBP1L | c.1660G>A p.E554K (on ENST00000271234 / NM_001164473.2; = p.E496K on NM_017737.5) | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, varscan2
- GRIK1 | c.1432T>C p.Y478H | Missense Mutation (SNP) | VAF 82/528 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- GRM3 | c.462C>T p.S154= | Silent (SNP) | VAF 25/204 reads (12%) | catalogued as rs776239124; called by muse, mutect2, varscan2
- GRM6 | c.1545G>A p.S515= | Silent (SNP) | VAF 27/520 reads (5%) | catalogued as rs375659197; called by muse, mutect2
- SLC26A3 | c.513C>T p.D171= | Silent (SNP) | VAF 148/420 reads (35%) | catalogued as rs367588993; called by muse, mutect2, varscan2
